Somatic mutation profile of tumor specimen 0DO2F9 from CCDI case PBCCCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 17.5 years (6,402 days).
Specimen 0DO2F9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27807534-690c-4922-99a4-39089084c8f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO2ER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6615d707-e12c-4a50-9577-1c577764b3c4

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Intron 6, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, 3'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 604/994 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFF1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.748); catalogued as rs148083475, COSV57124068; called by muse, mutect2, varscan2
- ANO6 | c.1816A>G p.T606A | Missense Mutation (SNP) | VAF 174/365 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs1303263585; called by muse, mutect2, varscan2
- ASB5 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 74/430 reads (17%) | catalogued as COSV56668461, COSV56670474; called by muse, mutect2, varscan2
- DIAPH3 | c.1481-1G>C p.X494_splice (on ENST00000400324 / NM_001042517.2; = p.X231_splice on NM_030932.3) | Splice Site (SNP) | VAF 25/270 reads (9%) | catalogued as COSV99934517; called by muse, mutect2
- DNAH2 | c.12409C>A p.Q4137K | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV101209419; called by muse, mutect2
- ERBB4 | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV53592079; called by muse, mutect2
- FAR2 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 28/996 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99479148; called by muse, mutect2
- FMO5 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 25/680 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs587653353; called by muse, mutect2
- KDM2B | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 40/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555292068; called by muse, mutect2
- NEB | c.10631C>T p.P3544L | Missense Mutation (SNP) | VAF 44/696 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200557002, COSV51429766; called by muse, mutect2
- OR2T29 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 55/488 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as COSV100148385; called by muse, mutect2, varscan2
- PRAM1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs749889447; called by muse, mutect2
- RANBP17 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 26/628 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV66658609; called by muse, mutect2
- SIGLEC12 | c.1567G>A p.D523N (on ENST00000291707 / NM_053003.4; = p.D405N on NM_033329.2) | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs1265743018; called by muse, mutect2, varscan2
- STAC | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749192922; called by muse, mutect2, varscan2
- TCF20 | c.2887G>A p.G963S | Missense Mutation (SNP) | VAF 52/457 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs200854743, COSV100167110; called by muse, mutect2, varscan2
- TRAF7 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV58213894, COSV58215141, COSV58216343; called by muse, mutect2
- TRIM58 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63570337; called by muse, mutect2, varscan2
- WNT9A | c.181del p.R61Gfs*2 | Frame Shift Del (DEL) | VAF 281/788 reads (36%) | catalogued as COSV99688195; called by mutect2, pindel, varscan2
- ZNF362 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 148/457 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs767449978; called by muse, mutect2, varscan2
- ZNF385D | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 60/542 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55745874; called by muse, mutect2
- ZNF48 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 42/582 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs368795388; called by muse, mutect2
- ZNF713 | c.1157A>T p.K386I (on ENST00000633730 / NM_001366796.2; = p.K399I on NM_182633.3) | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101448718; called by muse, mutect2, varscan2
- ZNF782 | c.1671_1672del p.E559Kfs*4 | Frame Shift Del (DEL) | VAF 111/400 reads (28%) | catalogued as rs372496151; called by mutect2, pindel, varscan2
- ANKRD27 | c.1993_1995del p.K665del | In Frame Del (DEL) | VAF 54/420 reads (13%) | called by pindel, varscan2
- DAXX | c.2220T>A p.D740E | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DIP2A | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FSIP2 | c.20336del p.K6779Rfs*16 | Frame Shift Del (DEL) | VAF 28/296 reads (9%) | called by mutect2, pindel, varscan2
- HAS1 | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL31 | c.407T>C p.F136S | Missense Mutation (SNP) | VAF 24/763 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- LAMA3 | c.6084A>C p.L2028F (on ENST00000313654 / NM_198129.4; = p.L419F on NM_000227.6) | Missense Mutation (SNP) | VAF 10/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NCBP1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 130/410 reads (32%) | called by mutect2, varscan2
- OR10P1 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 120/482 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OR2T5 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 113/1250 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OVCH1 | c.1757G>T p.W586L | Missense Mutation (SNP) | VAF 38/1104 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- PDZD4 | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2
- PKHD1L1 | c.11553+1G>A p.X3851_splice | Splice Site (SNP) | VAF 26/562 reads (5%) | called by muse, mutect2
- PRKRA | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 80/497 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PRPF4 | c.1222G>T p.E408* (on ENST00000374198 / NM_001322267.2; = p.E409* on NM_004697.5) | Nonsense Mutation (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- RTL9 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SALL1 | c.3951C>G p.D1317E | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- SCRIB | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 192/623 reads (31%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SIRT6 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- SLC25A19 | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 102/652 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC9A4 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- TMEM132E | c.1010C>A p.A337E (on ENST00000321639; = p.A427E on NM_001304438.2) | Missense Mutation (SNP) | VAF 25/603 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2
- ZNF117 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- ZNF648 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 107/695 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZSCAN29 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ADGRL1 | c.3165G>A p.A1055= (on ENST00000340736 / NM_001008701.3; = p.A1050= on NM_014921.5) | Silent (SNP) | VAF 26/356 reads (7%) | catalogued as rs760966469; called by muse, mutect2
- ALOX15B | c.2025C>T p.S675= | Silent (SNP) | VAF 70/371 reads (19%) | catalogued as rs1031648035, COSV101205658; called by muse, mutect2, varscan2
- CCDC17 | c.423G>T p.L141= | Silent (SNP) | VAF 79/470 reads (17%) | called by muse, mutect2, varscan2
- CD44 | c.540C>T p.S180= | Silent (SNP) | VAF 40/540 reads (7%) | catalogued as rs376873830, COSV99555997; called by muse, mutect2
- CDYL2 | c.339G>T p.L113= | Silent (SNP) | VAF 12/366 reads (3%) | called by muse, mutect2
- FEZF2 | c.51C>T p.R17= | Silent (SNP) | VAF 17/407 reads (4%) | called by muse, mutect2
- FRAS1 | c.8526C>T p.D2842= | Silent (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- MCM3AP | c.2388G>A p.K796= | Silent (SNP) | VAF 26/501 reads (5%) | catalogued as rs1064364; called by muse, mutect2
- NRAP | c.498C>A p.G166= | Silent (SNP) | VAF 114/480 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.17703C>T p.H5901= | Silent (SNP) | VAF 24/518 reads (5%) | called by muse, mutect2
- OS9 | c.1705C>T p.L569= | Silent (SNP) | VAF 74/784 reads (9%) | called by muse, mutect2
- POLQ | c.3165C>T p.S1055= | Silent (SNP) | VAF 67/507 reads (13%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1971G>A p.Q657= | Silent (SNP) | VAF 30/910 reads (3%) | called by muse, mutect2
- ADAM32 | c.834-30T>A | Intron (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- ALB | c.1429-46T>G | Intron (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.4169-63G>C | Intron (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- FAM238B | n.398-9C>A | Intron (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- LMNTD2 | c.555+81G>A | Intron (SNP) | VAF 18/197 reads (9%) | catalogued as rs546287594; called by muse, mutect2
- NEB | c.18454-22T>C | Intron (SNP) | VAF 28/383 reads (7%) | called by muse, mutect2
- NR1I3 | c.*54G>T | 3'UTR (SNP) | VAF 40/869 reads (5%) | called by muse, mutect2
- VAX1 | chr10:117132115 A>T | 3'Flank (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
